TCGA case TCGA-QR-A6GT — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Retroperitoneum and peritoneum; Tissue source site: National Institutes of Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08dd606a-1982-4cb9-bcd6-09d4bc158f6d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (4)
1. Pheochromocytoma, NOS (the primary disease): ICD-O-3 morphology code: 8700/0; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 63.5 years (23,208 days); Year of diagnosis: 2002; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,185 days (11.5 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 2.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 2,266 days (6.2 years); Days to treatment end: 2,266 days (6.2 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dacarbazine + Vincristine; Days to treatment start: 2,435 days (6.7 years); Days to treatment end: 3,452 days (9.5 years); Treatment outcome: Partial Response; Clinical trial indicator: Yes.
2. Metastasis of diagnosis 1 (Pheochromocytoma, NOS), site: Lung, NOS. Age at diagnosis: 67.6 years (24,684 days); Days to diagnosis: 1,476 days (4.0 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Pheochromocytoma, NOS), site: Bone, NOS. Age at diagnosis: 67.6 years (24,684 days); Days to diagnosis: 1,476 days (4.0 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Pheochromocytoma, NOS), site: Liver. Age at diagnosis: 67.6 years (24,684 days); Days to diagnosis: 1,476 days (4.0 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Day 1,476 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,476 days (4.0 years); Evidence of progression type: Convincing Image Source.
- Day 1,476 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,476 days (4.0 years); Evidence of progression type: Convincing Image Source.
- Day 1,476 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 1,476 days (4.0 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 4,185 days (11.5 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QR-A6GT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 170 mg.
  Slide TCGA-QR-A6GT-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QR-A6GT-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QR-A6GT-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease.
- Primary pathology: Submitted tumor site: Extra-adrenal Site; Site of primary tumor other: Perirenal mass; Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Pheochromocytoma; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- Drug treatment: Pharmaceutical therapy drug name: Cytoxan, vincristine and dacarbazine.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,185 days; disease-specific survival: no event (censored), 4,185 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,476 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QR-A6GT-01A-11D-A35C-01): tumor purity 0.59, ploidy 1.85, whole-genome doublings 0.
